Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45O, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45O-01A (Primary Tumor).

[page 1 of 2]
Discrepancy		

DB: _____ Sex: M
Physician: _____

Received _____ Pathologist: _____ Accession: _____
Case type: Surgical History

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT

RECD:
DXCD :
CONSULTANT: _____ TO:
TIME RECD:
PHOTO: COMPOSITE RES. R MANDIBLE
DX COMPLETED:

D:N
SUPPLEMENTAL REPORT

DIAGNOSIS :
(C) COMPOSITE RESECTION OF ALVEOLAR RIDGE:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED
INVOLVING ALVEOLAR BONE.
Anterior and posterior mandibular margins of resection free of
tumor. (see comment)
COMMENT: This supplemental report is issued to comment on the decalcified
bone and bone margin. This report does not alter any of the prior
diagnosis given on the original report.

1CA-0-3
Carcinoma, Squamous cell, NOS 8070/3
Site: alveolar ridge, NOS C03.9

DIAGNOSIS
(A) LEFT MIDDLE JUGULAR LYMPH NODE AND FAT:
One lymph node, no tumor present.
Fibrovascular and adipose tissue, no tumor present.
(B) LEFT SUPRAOMOHYOID NECK DISSECTION:
Thirteen cervical lymph nodes, no tumor present (6 submental-
submaxillary, 2 subdigastic, 4 midjugular and 1 upper
posterior cervical).
Submaxillary salivary gland, no tumor present.
(C) COMPOSITE RESECTION OF ALVEOLAR RIDGE:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED,
INVOLVING ANTERIOR AND MEDIAL SOFT TISSUE MARGINS. TUMOR
GROSSLY MEASURED 3.0 X 1.2 X 1.0 CM. (SEE COMMENT)
DEPTH OF TUMOR INVASION INTO SOFT TISSUES IS 0.9 CM.
Bone and bone margins pending decalcification, supplemental
report to follow.
(D) NEW ANTERIOR MEDIAL MARGIN:
Squamous mucosa, no tumor present. (See comment)
(E) TEETH:
Four teeth (gross only).

COMMENT
The final mucosal and soft tissue margins of resection are free of
tumor.

[page 2 of 2]
DOB:

Sex: M

Physician:

Received:

Pathologist

Accession:

Case type: Surgical History

SPECIMEN

PHOTO: COMPOSITE RES.R MANDIBLE

SNOMED CODES

T-11180,M-80703

Source: NCI Genomic Data Commons file fd9c9978-1c5d-4e61-ab8a-1158a1d793c5 (TCGA-CV-A45O.99BDB118-D387-4BE6-B567-6212E87B63E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).